Somatic mutation profile of tumor specimen C3N-03234-02 (aliquot CPT0180900006) from CPTAC case C3N-03234, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 62.2 years (22,717 days).
Specimen C3N-03234-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 364c924e-5ea4-44d3-8d21-50a8250684d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03234-71 (Blood Derived Normal), aliquot CPT0181010002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a923242f-f30f-49b9-9976-8693f4b6ba0f

The open-access MAF lists 887 somatic variants for this specimen: 548 protein-altering or splice-affecting, 302 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 498, Silent 302, Nonsense Mutation 28, Intron 26, Splice Region 18, Splice Site 3, 3'UTR 3, 3'Flank 3, 5'Flank 3, 5'UTR 1, Translation Start Site 1, RNA 1.

Variants (750 of 887; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX3X | c.1700C>T p.P567L (on ENST00000399959; = p.P568L on NM_001356.5) | Missense Mutation (SNP) | VAF 23/217 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519430, CM158051, COSV67863241; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 29/370 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2
- RPE65 | c.130C>T p.R44* | Nonsense Mutation (SNP) | VAF 30/390 reads (8%) | catalogued as rs368088025, CM167086; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- TGFB2 | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 20/490 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1057521150, CM1210057, COSV65108222, COSV65109328; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ABAT | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 24/292 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51626539; called by muse, mutect2
- ABCA13 | c.14878G>A p.E4960K | Missense Mutation (SNP) | VAF 50/379 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as COSV101291195; called by muse, mutect2, varscan2
- ABCB1 | c.1169G>A p.G390E | Missense Mutation (SNP) | VAF 29/374 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55958562, COSV55958958; called by muse, mutect2
- ABCC3 | c.2414G>A p.R805Q | Missense Mutation (SNP) | VAF 22/304 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99035150; called by muse, mutect2
- ABHD14A-ACY1 | c.533A>G p.E178G | Missense Mutation (SNP) | VAF 14/351 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.011); catalogued as rs1388988899; called by muse, mutect2
- ACTL7B | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 37/393 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752064414; called by muse, mutect2
- ADAM19 | c.1202G>A p.G401E | Missense Mutation (SNP) | VAF 24/460 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV57433129, COSV99976106; called by muse, mutect2
- ADGRB1 | c.3875C>T p.P1292L | Missense Mutation (SNP) | VAF 20/636 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1175986636; called by muse, mutect2
- ADGRB2 | c.3575C>T p.S1192F | Missense Mutation (SNP) | VAF 30/450 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1286156848; called by muse, mutect2
- ANK2 | c.5537C>T p.S1846L | Missense Mutation (SNP) | VAF 36/444 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.356); catalogued as rs1563997337; called by muse, mutect2
- ANK3 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 24/360 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV55046849; called by muse, mutect2
- ANKEF1 | c.743C>T p.S248L | Missense Mutation (SNP) | VAF 34/276 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.025); catalogued as rs145101692; called by muse, mutect2
- ANKRD18A | c.2189G>A p.G730E | Missense Mutation (SNP) | VAF 24/320 reads (8%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.994); catalogued as COSV68804038; called by muse, mutect2
- ANKRD18A | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 18/418 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.293); catalogued as rs1388061883; called by muse, mutect2
- ANO3 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 15/284 reads (5%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs1254525478, COSV56784546; called by muse, mutect2
- AP5B1 | c.1375C>T p.R459W | Missense Mutation (SNP) | VAF 48/502 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs531833936; called by muse, mutect2
- ARHGAP29 | c.2284G>A p.E762K | Missense Mutation (SNP) | VAF 12/201 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.801); catalogued as COSV53108515; called by muse, mutect2
- ARHGEF16 | c.392C>T p.S131F | Missense Mutation (SNP) | VAF 46/572 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs550096684; called by muse, mutect2
- ARMC2 | c.1748C>T p.P583L | Missense Mutation (SNP) | VAF 37/536 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs753578946; called by muse, mutect2
- ASB5 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 23/398 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.572); catalogued as rs1247396254; called by muse, mutect2
- ATP10D | c.1466C>T p.S489F | Missense Mutation (SNP) | VAF 18/357 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.707); catalogued as COSV56703393; called by muse, mutect2
- ATP1A1 | c.328C>A p.L110I | Missense Mutation (SNP) | VAF 26/484 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.974); catalogued as COSV55191537, COSV99814772; called by muse, mutect2
- AVPR1A | c.1175G>A p.R392Q | Missense Mutation (SNP) | VAF 31/442 reads (7%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.986); catalogued as rs1424319046, COSV54547616; called by muse, mutect2
- BATF3 | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 23/358 reads (6%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.914); catalogued as rs1395373528, COSV54658069; called by muse, mutect2
- BICC1 | c.977C>T p.P326L | Missense Mutation (SNP) | VAF 36/494 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.121); catalogued as rs778645337; called by muse, mutect2
- C10orf120 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 29/458 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.077); catalogued as rs746651873, COSV61492288; called by muse, mutect2
- C3AR1 | c.441G>A p.W147* | Nonsense Mutation (SNP) | VAF 30/507 reads (6%) | catalogued as COSV50820412; called by muse, mutect2
- C9 | c.434G>A p.R145K | Missense Mutation (SNP) | VAF 25/401 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV54677424, COSV54679291; called by muse, mutect2
- CADM2 | c.626C>T p.S209F (on ENST00000407528 / NM_001167674.2; = p.S211F on NM_153184.4) | Missense Mutation (SNP) | VAF 26/404 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV67411544; called by muse, mutect2
- CAPZA3 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 32/456 reads (7%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.922); catalogued as rs1354351578; called by muse, mutect2
- CCDC178 | c.640C>T p.P214S | Missense Mutation (SNP) | VAF 19/314 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1314108944, COSV55764637; called by muse, mutect2
- CCDC33 | c.1720G>A p.D574N | Missense Mutation (SNP) | VAF 21/372 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.461); catalogued as rs1443936059; called by muse, mutect2
- CCDC9B | c.812C>T p.S271F | Missense Mutation (SNP) | VAF 21/348 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as rs867686873; called by muse, mutect2
- CCNT1 | c.1697C>T p.S566F | Missense Mutation (SNP) | VAF 21/298 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.38); catalogued as rs1164245033; called by muse, mutect2
- CDC42EP4 | c.521C>T p.S174F | Missense Mutation (SNP) | VAF 50/460 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.111); catalogued as rs768798899; called by muse, mutect2, varscan2
- CEACAM5 | c.385C>T p.L129F | Missense Mutation (SNP) | VAF 18/373 reads (5%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.513); catalogued as rs1555813786; called by muse, mutect2
- CFAP46 | c.1714G>A p.E572K | Missense Mutation (SNP) | VAF 26/378 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs915496495; called by muse, mutect2
- CFAP54 | c.6404C>T p.S2135F | Missense Mutation (SNP) | VAF 13/282 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV61576159; called by muse, mutect2
- CFHR4 | c.149C>T p.S50F (on ENST00000367416 / NM_001201551.2; = p.S51F on NM_006684.5) | Missense Mutation (SNP) | VAF 25/345 reads (7%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.852); catalogued as rs1291256909; called by muse, mutect2
- CHST13 | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 29/426 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV60041286; called by muse, mutect2
- CNDP1 | c.265G>A p.G89R | Missense Mutation (SNP) | VAF 40/416 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100722230; called by muse, mutect2
- CNR1 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 24/326 reads (7%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV62986649; called by muse, mutect2
- COL11A1 | c.1540G>A p.A514T | Missense Mutation (SNP) | VAF 16/377 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV62182816; called by muse, mutect2
- COL3A1 | c.2738C>T p.A913V | Missense Mutation (SNP) | VAF 23/409 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV58585674; called by muse, mutect2
- CPB2 | c.555G>A p.W185* | Nonsense Mutation (SNP) | VAF 27/335 reads (8%) | catalogued as rs374341270; called by muse, mutect2
- CPLX1 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 30/508 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV58375413; called by muse, mutect2
- CROCC2 | c.1990G>A p.E664K | Missense Mutation (SNP) | VAF 22/505 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.377); catalogued as rs1473329904; called by muse, mutect2
- CRPPA | c.550C>T p.R184* | Nonsense Mutation (SNP) | VAF 28/232 reads (12%) | catalogued as rs370499190, CM123226; called by muse, mutect2, varscan2
- CRYBA4 | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 46/299 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1459497417; called by muse, mutect2, varscan2
- CRYBG1 | c.5701C>T p.R1901C | Missense Mutation (SNP) | VAF 24/324 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779661246; called by muse, mutect2
- CSNKA2IP | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 22/318 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs935252709, COSV68072668; called by muse, mutect2
- CTCF | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 28/397 reads (7%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.026); catalogued as COSV50464592; called by muse, mutect2
- DDX27 | c.1178C>T p.S393F | Missense Mutation (SNP) | VAF 33/411 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1383330129, COSV65607997; called by muse, mutect2
- DGCR8 | c.1765C>T p.P589S | Missense Mutation (SNP) | VAF 34/347 reads (10%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.838); catalogued as rs769125792; called by muse, mutect2
- DGKI | c.1406G>A p.R469Q | Missense Mutation (SNP) | VAF 44/394 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55941877; called by muse, mutect2
- DNAH2 | c.3838G>A p.D1280N | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.06); catalogued as COSV101209502; called by muse, mutect2
- DNAH5 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 16/308 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); catalogued as COSV54226681; called by muse, mutect2
- DNTTIP1 | c.652C>T p.R218* | Nonsense Mutation (SNP) | VAF 43/366 reads (12%) | catalogued as rs1231521875, COSV65460704; called by muse, mutect2, varscan2
- DSC3 | c.1390G>A p.D464N | Missense Mutation (SNP) | VAF 22/464 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.162); catalogued as COSV64572766; called by muse, mutect2
- DSG2 | c.2093G>A p.G698E | Missense Mutation (SNP) | VAF 43/345 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as COSV55199026, COSV55202884; called by muse, mutect2, varscan2
- DTX2 | c.1412C>T p.S471F | Missense Mutation (SNP) | VAF 50/390 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as rs1227058808; called by muse, mutect2, varscan2
- DZIP1 | c.2035C>T p.P679S (on ENST00000347108; = p.P660S on NM_014934.5) | Missense Mutation (SNP) | VAF 14/276 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV61267416; called by muse, mutect2
- ELN | c.475C>T p.R159W | Missense Mutation (SNP) | VAF 26/430 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs1273222616, COSV99332883; called by muse, mutect2
- ENTPD6 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 26/492 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.697); catalogued as rs961167267; called by muse, mutect2
- EPHB1 | c.1231G>A p.G411R | Missense Mutation (SNP) | VAF 36/412 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67671252; called by muse, mutect2
- FAM193B | c.2179C>T p.P727S | Missense Mutation (SNP) | VAF 18/434 reads (4%) | SIFT tolerated (0.46); PolyPhen benign (0.296); catalogued as rs1380400532; called by muse, mutect2
- FAM20B | c.868C>G p.R290G | Missense Mutation (SNP) | VAF 28/427 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55379898; called by muse, mutect2
- FAM81A | c.206G>A p.G69E | Missense Mutation (SNP) | VAF 32/508 reads (6%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs1277100664, COSV99893279; called by muse, mutect2
- FAT4 | c.5525C>T p.S1842F | Missense Mutation (SNP) | VAF 20/300 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58677521; called by muse, mutect2
- FCHO1 | c.2621C>T p.S874L | Missense Mutation (SNP) | VAF 27/343 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1215872386, COSV53182184; called by muse, mutect2
- FCRL3 | c.1295G>A p.G432E | Missense Mutation (SNP) | VAF 30/357 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV100943169; called by muse, mutect2
- FLNB | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 24/310 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99911831; called by muse, mutect2
- FMN2 | c.4882G>A p.E1628K | Missense Mutation (SNP) | VAF 16/382 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.505); catalogued as COSV60425836; called by muse, mutect2
- FOXI3 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 23/484 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as COSV67916796; called by muse, mutect2
- FSIP1 | c.1291A>C p.K431Q | Missense Mutation (SNP) | VAF 27/334 reads (8%) | SIFT tolerated (0.74); PolyPhen benign (0.033); catalogued as rs909102181; called by muse, mutect2
- FUS | c.857C>T p.T286I | Missense Mutation (SNP) | VAF 30/370 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99568360; called by muse, mutect2
- FYTTD1 | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 34/402 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54082603; called by muse, mutect2
- GABRP | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 16/388 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.42); catalogued as COSV54664661; called by muse, mutect2
- GDAP1L1 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 42/504 reads (8%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.908); catalogued as rs903676954; called by muse, mutect2
- GLI2 | c.3440C>T p.P1147L (on ENST00000361492 / NM_001374353.1; = p.P1164L on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/498 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs1357654147; called by muse, mutect2
- GRIA3 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 38/263 reads (14%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.973); catalogued as COSV52074235; called by muse, mutect2, varscan2
- GRID2 | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 18/430 reads (4%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.465); catalogued as COSV56221072; called by muse, mutect2
- GTPBP1 | c.1238C>T p.S413L | Missense Mutation (SNP) | VAF 28/346 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53285791; called by muse, mutect2
- HMCN1 | c.4915C>T p.P1639S | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54873269; called by muse, mutect2
- HMCN1 | c.11660G>A p.R3887K | Missense Mutation (SNP) | VAF 14/276 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.982); catalogued as COSV54904172, COSV54930577; called by muse, mutect2
- HYAL3 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 30/478 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs782052254; called by muse, mutect2
- IFT27 | c.349C>T p.P117S (on ENST00000433985 / NM_001363003.2; = p.P116S on NM_006860.5) | Missense Mutation (SNP) | VAF 33/338 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100503613; called by muse, mutect2
- IL20RA | c.1376C>T p.P459L | Missense Mutation (SNP) | VAF 21/403 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.053); catalogued as rs1435608517, COSV100359787; called by muse, mutect2
- INPP5J | c.2803G>A p.G935S (on ENST00000331075 / NM_001284285.2; = p.G567S on NM_001002837.2) | Missense Mutation (SNP) | VAF 50/518 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.158); catalogued as rs1173989165; called by muse, mutect2
- INPP5J | c.2804G>A p.G935D (on ENST00000331075 / NM_001284285.2; = p.G567D on NM_001002837.2) | Missense Mutation (SNP) | VAF 48/465 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.779); catalogued as rs553032524; called by muse, mutect2, varscan2
- KCNT1 | c.213C>A p.F71L (on ENST00000488444; = p.F90L on NM_020822.3) | Missense Mutation (SNP) | VAF 26/370 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.109); catalogued as COSV53695892; called by muse, mutect2
- KIAA1210 | c.2369G>A p.G790E | Missense Mutation (SNP) | VAF 31/224 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.048); catalogued as rs1410279324; called by muse, mutect2, varscan2
- KIAA1671 | c.263C>T p.S88L | Missense Mutation (SNP) | VAF 73/556 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1360461585; called by muse, mutect2, varscan2
- KIFC2 | c.2423G>A p.R808Q | Missense Mutation (SNP) | VAF 43/610 reads (7%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.066); catalogued as rs372870601, COSV56759627; called by muse, mutect2
- KLRG2 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 20/444 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.12); catalogued as rs930847497, COSV61800500; called by muse, mutect2
- KMT2A | c.6605C>T p.P2202L | Missense Mutation (SNP) | VAF 21/396 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); catalogued as rs1456050279, COSV104417938; called by muse, mutect2
- KRT75 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 32/360 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52874629; called by muse, mutect2
- KRTAP5-10 | c.395G>A p.G132E | Missense Mutation (SNP) | VAF 26/322 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.36); catalogued as rs1394117609, COSV64794414; called by muse, mutect2
- LAMB1 | c.2387C>T p.P796L | Missense Mutation (SNP) | VAF 30/508 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55965996; called by muse, mutect2
- LAMC2 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 28/352 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.489); catalogued as rs374263073; called by muse, mutect2
- LAT2 | c.135G>A p.L45= | Splice Region (SNP) | VAF 58/397 reads (15%) | catalogued as rs368953885; called by muse, mutect2, varscan2
- LHFPL1 | c.26G>A p.G9E | Missense Mutation (SNP) | VAF 29/213 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as COSV64333421; called by muse, mutect2, varscan2
- LINC02218 | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 20/412 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as rs868109331; called by muse, mutect2
- LPAR3 | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 25/419 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101004885; called by muse, mutect2
- LRIT2 | c.479C>T p.S160F | Missense Mutation (SNP) | VAF 22/374 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs1169579409; called by muse, mutect2
- LRP1B | c.13325G>A p.R4442K | Missense Mutation (SNP) | VAF 15/252 reads (6%) | SIFT tolerated (0.94); PolyPhen benign (0.099); catalogued as COSV101262055; called by muse, mutect2
- LRP1B | c.12596G>A p.G4199E | Missense Mutation (SNP) | VAF 18/291 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs868543953, COSV67186838; called by muse, mutect2
- LRP5 | c.3166G>A p.E1056K | Missense Mutation (SNP) | VAF 36/578 reads (6%) | SIFT tolerated (0.7); PolyPhen benign (0.041); catalogued as rs751521743; called by muse, mutect2
- LRRC57 | c.484C>T p.Q162* | Nonsense Mutation (SNP) | VAF 15/164 reads (9%) | catalogued as COSV52999878; called by muse, mutect2
- LRRC7 | c.1525G>A p.E509K (on ENST00000651989 / NM_001370785.2; = p.E476K on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/225 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as rs1318855534, COSV50409067; called by muse, mutect2
- LRRIQ1 | c.3520T>C p.F1174L | Missense Mutation (SNP) | VAF 26/292 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV67825919; called by muse, mutect2
- LZTS3 | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 31/362 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs751027312; called by muse, mutect2
- MAGEB2 | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 23/219 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.678); catalogued as rs1289765940; called by muse, mutect2, varscan2
- MAIP1 | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 15/492 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as COSV54461691; called by muse, mutect2
- MAST1 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 34/549 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1277122500; called by muse, mutect2
- MAT2A | c.406G>A p.G136S | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52088088; called by muse, mutect2
- MDH1 | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 16/328 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV51862244; called by muse, mutect2
- MED14 | c.2950C>T p.P984S | Missense Mutation (SNP) | VAF 32/270 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV61356878; called by muse, mutect2, varscan2
- MEGF10 | c.650C>T p.T217I | Missense Mutation (SNP) | VAF 25/265 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.598); catalogued as COSV57245307; called by muse, mutect2
- MIGA1 | c.667C>T p.R223* | Nonsense Mutation (SNP) | VAF 26/359 reads (7%) | catalogued as rs747991246; called by muse, mutect2
- MINDY4B | c.1301G>A p.R434Q | Missense Mutation (SNP) | VAF 21/436 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.106); catalogued as rs1434122474; called by muse, mutect2
- MRPL20 | c.262G>A p.G88R | Missense Mutation (SNP) | VAF 16/356 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0.121); catalogued as COSV61224168; called by muse, mutect2
- MUC16 | c.26950C>T p.P8984S | Missense Mutation (SNP) | VAF 38/470 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.039); catalogued as rs762298173; called by muse, mutect2
- MUC16 | c.3208G>A p.D1070N | Missense Mutation (SNP) | VAF 15/436 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.486); catalogued as rs965434261; called by muse, mutect2
- MUC17 | c.1472C>T p.S491L | Missense Mutation (SNP) | VAF 39/339 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as rs780074683, COSV60289794; called by muse, mutect2, varscan2
- MUC17 | c.7150G>A p.D2384N | Missense Mutation (SNP) | VAF 58/476 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs577539877, COSV60286368; called by muse, mutect2, varscan2
- MYH7 | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 16/374 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62522714; called by muse, mutect2
- MYO5C | c.4900C>T p.L1634F | Missense Mutation (SNP) | VAF 22/466 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99954167; called by muse, mutect2
- NAV3 | c.3125G>A p.G1042E | Missense Mutation (SNP) | VAF 18/430 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99886838; called by muse, mutect2
- NEK2 | c.887C>T p.S296L | Missense Mutation (SNP) | VAF 22/347 reads (6%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1372194983, COSV65355244; called by muse, mutect2
- NEO1 | c.3910C>T p.R1304* | Nonsense Mutation (SNP) | VAF 20/240 reads (8%) | catalogued as rs1194933780, COSV56067714; called by muse, mutect2
- NFAT5 | c.2609C>T p.P870L | Missense Mutation (SNP) | VAF 22/431 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV100590686; called by muse, mutect2
- NLRP11 | c.2812C>T p.L938F | Missense Mutation (SNP) | VAF 18/367 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as COSV64088777; called by muse, mutect2
- NLRP13 | c.1063C>T p.P355S | Missense Mutation (SNP) | VAF 31/426 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61620786; called by muse, mutect2
- NLRP4 | c.1499G>T p.G500V | Missense Mutation (SNP) | VAF 21/486 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV56715158, COSV56718184; called by muse, mutect2
- NLRP5 | c.2225G>A p.G742E | Missense Mutation (SNP) | VAF 34/466 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV66768011; called by muse, mutect2
- NMNAT3 | c.470T>C p.V157A (on ENST00000296202 / NM_001320512.1; = p.V120A on NM_178177.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/496 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.89); catalogued as rs1401758266; called by muse, mutect2
- NPAP1 | c.2371G>A p.D791N | Missense Mutation (SNP) | VAF 15/439 reads (3%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.437); catalogued as COSV61504466; called by muse, mutect2
- NPHP4 | c.1514C>T p.S505F | Missense Mutation (SNP) | VAF 18/334 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1389549742; called by muse, mutect2
- NPR1 | c.1935G>A p.K645= | Splice Region (SNP) | VAF 32/372 reads (9%) | catalogued as rs1275586062, COSV64117745; called by muse, mutect2
- NR3C2 | c.2818G>A p.E940K | Missense Mutation (SNP) | VAF 20/221 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.121); catalogued as COSV60998007; called by muse, mutect2
- NTN4 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 20/288 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs769530917, COSV100643767; called by muse, mutect2
- NUDCD1 | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 25/316 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV53459354; called by muse, mutect2
- NUDCD1 | c.1431G>A p.W477* | Nonsense Mutation (SNP) | VAF 25/323 reads (8%) | catalogued as COSV53454439; called by muse, mutect2
- NUP210L | c.3948G>A p.R1316= | Splice Region (SNP) | VAF 19/242 reads (8%) | catalogued as COSV55155832; called by muse, mutect2
- ODF3L2 | c.348G>A p.R116= | Splice Region (SNP) | VAF 20/246 reads (8%) | catalogued as COSV100205480; called by muse, mutect2
- OR11L1 | c.486G>A p.M162I | Missense Mutation (SNP) | VAF 24/404 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV63313995; called by muse, mutect2
- OR1Q1 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 19/411 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1329146653; called by muse, mutect2
- OR2AJ1 | c.563C>T p.S188F | Missense Mutation (SNP) | VAF 18/416 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.201); catalogued as rs935108321; called by muse, mutect2
- OR2J3 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 20/330 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.067); catalogued as COSV65848776, COSV65849417; called by muse, mutect2
- OR4D5 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 29/390 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs138187932; called by muse, mutect2
- OR6C6 | c.41G>A p.G14E | Missense Mutation (SNP) | VAF 18/285 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.901); catalogued as rs981517436; called by muse, mutect2
- OR6S1 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 34/447 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as rs755506112, COSV57837652; called by muse, mutect2
- P4HA2 | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 33/350 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV51333591; called by muse, mutect2
- PCLO | c.9287C>T p.P3096L | Missense Mutation (SNP) | VAF 40/408 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61665232; called by muse, mutect2, varscan2
- PERCC1 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 32/575 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.482); catalogued as rs1409351057; called by muse, mutect2
- PIK3C2B | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 42/426 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.146); catalogued as COSV65803521; called by muse, mutect2
- PIP5K1B | c.814G>A p.G272R | Missense Mutation (SNP) | VAF 20/376 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99598534; called by muse, mutect2
- PKP3 | c.1837C>T p.R613W | Missense Mutation (SNP) | VAF 35/548 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs753469135; called by muse, mutect2
- PLCB4 | c.1486G>A p.D496N | Missense Mutation (SNP) | VAF 29/322 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.335); catalogued as rs1417852261, COSV53801654, COSV53802129; called by muse, mutect2
- PLEKHG6 | c.1798G>A p.G600R | Missense Mutation (SNP) | VAF 31/421 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.169); catalogued as COSV50600093; called by muse, mutect2
- PNLIPRP3 | c.1370G>A p.G457E | Missense Mutation (SNP) | VAF 22/276 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs550696709; called by muse, mutect2
- PRAMEF1 | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 46/532 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.37); catalogued as COSV60013436; called by muse, mutect2
- PRG4 | c.3304G>A p.G1102R | Missense Mutation (SNP) | VAF 28/390 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV63355028; called by muse, mutect2
- PRKG2 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 14/245 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.065); catalogued as rs867660938, COSV52320273; called by muse, mutect2
- PTCHD3 | c.2263G>A p.D755N | Missense Mutation (SNP) | VAF 18/488 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1308846174; called by muse, mutect2
- PTGIS | c.1162T>C p.F388L | Missense Mutation (SNP) | VAF 25/526 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.59); catalogued as rs973616051; called by muse, mutect2
- PTPRC | c.3510G>A p.R1170= | Splice Region (SNP) | VAF 11/252 reads (4%) | catalogued as rs1421608327, COSV100723023; called by muse, mutect2
- PTPRD | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 21/430 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.091); catalogued as COSV61927295; called by muse, mutect2
- PTPRH | c.1139G>A p.R380Q | Missense Mutation (SNP) | VAF 36/338 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as rs769189088, COSV54744501; called by muse, mutect2
- PTPRZ1 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as rs376460185; called by muse, mutect2, varscan2
- PVRIG | c.55G>A p.G19R | Missense Mutation (SNP) | VAF 49/448 reads (11%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.005); catalogued as rs776476006; called by muse, mutect2, varscan2
- PXDNL | c.2294G>A p.R765H | Missense Mutation (SNP) | VAF 27/498 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100685952; called by muse, mutect2
- RAB11B | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 23/527 reads (4%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.281); catalogued as rs1299045693, COSV60086418; called by muse, mutect2
- RASIP1 | c.2639G>A p.G880E | Missense Mutation (SNP) | VAF 44/604 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV55806589; called by muse, mutect2
- RASIP1 | c.2638G>A p.G880R | Missense Mutation (SNP) | VAF 45/606 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs746217873, COSV55806606; called by muse, mutect2
- RELN | c.6853C>T p.R2285C | Missense Mutation (SNP) | VAF 46/424 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs144565023; called by muse, mutect2, varscan2
- RFPL4B | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 31/332 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.26); catalogued as rs562746815, COSV71437659; called by muse, mutect2
- RGL4 | c.535G>A p.G179R | Missense Mutation (SNP) | VAF 65/474 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.77); catalogued as rs753877584; called by muse, mutect2, varscan2
- RGPD4 | c.2263G>A p.E755K | Missense Mutation (SNP) | VAF 31/310 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs746649494; called by muse, mutect2, varscan2
- RHBG | c.1030C>T p.L344F | Missense Mutation (SNP) | VAF 32/457 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760456915; called by muse, mutect2
- RIN3 | c.956C>T p.A319V | Missense Mutation (SNP) | VAF 10/265 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs1452446612; called by muse, mutect2
- RNF128 | c.641C>T p.S214F (on ENST00000255499 / NM_194463.2; = p.S188F on NM_024539.3) | Missense Mutation (SNP) | VAF 15/194 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55255616; called by muse, mutect2
- RPTN | c.1489T>C p.Y497H | Missense Mutation (SNP) | VAF 34/524 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.17); catalogued as COSV60167258; called by muse, mutect2
- RTP1 | c.367G>A p.V123M | Missense Mutation (SNP) | VAF 34/544 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs768259250; called by muse, mutect2
- RXFP1 | c.1466G>A p.G489E | Missense Mutation (SNP) | VAF 22/399 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100313948, COSV57055290; called by muse, mutect2
- SAMD7 | c.473G>A p.R158K | Missense Mutation (SNP) | VAF 23/412 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as COSV59417498; called by muse, mutect2
- SCN10A | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 31/486 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71862225, COSV71862558; called by muse, mutect2
- SCN2A | c.5617G>A p.D1873N | Missense Mutation (SNP) | VAF 37/459 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99333915; called by muse, mutect2
- SCRIB | c.2479C>T p.P827S | Missense Mutation (SNP) | VAF 55/701 reads (8%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.916); catalogued as rs781892146; called by muse, mutect2
- SDK1 | c.3815G>A p.R1272Q | Missense Mutation (SNP) | VAF 27/391 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.421); catalogued as rs758245711, COSV67386071; called by muse, mutect2
- SEC14L6 | c.973G>A p.G325R | Missense Mutation (SNP) | VAF 50/465 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as rs1405574208, COSV67857775; called by muse, mutect2, varscan2
- SERPINE3 | c.854G>A p.W285* | Nonsense Mutation (SNP) | VAF 24/442 reads (5%) | catalogued as rs1244956520; called by muse, mutect2
- SGCB | c.937C>T p.P313S | Missense Mutation (SNP) | VAF 20/273 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs960868232; called by muse, mutect2
- SHC3 | c.664G>A p.G222R | Missense Mutation (SNP) | VAF 17/353 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65437957; called by muse, mutect2
- SLC25A47 | c.830G>A p.G277E | Missense Mutation (SNP) | VAF 27/403 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs868019775; called by muse, mutect2
- SLC45A4 | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 27/500 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1422027374; called by muse, mutect2
- SLIT3 | c.4093G>A p.D1365N | Missense Mutation (SNP) | VAF 31/456 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as rs770091737, COSV60594584; called by muse, mutect2
- SNAPC4 | c.1936C>T p.H646Y | Missense Mutation (SNP) | VAF 28/560 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.13); catalogued as rs1269008809; called by muse, mutect2
- SNX13 | c.2279C>T p.S760L | Missense Mutation (SNP) | VAF 17/384 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.105); catalogued as rs1377093430, COSV68067433; called by muse, mutect2
- SP100 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 16/287 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); catalogued as rs1472834401, COSV50987020; called by muse, mutect2
- SPEM3 | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 20/438 reads (5%) | SIFT tolerated, low confidence (0.49); PolyPhen possibly damaging (0.651); catalogued as rs1168863289; called by muse, mutect2
- SPG11 | c.4562C>T p.S1521L | Missense Mutation (SNP) | VAF 30/463 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV99969802; called by muse, mutect2
- SSTR4 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 30/553 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as rs1477177527, COSV99658461; called by muse, mutect2
- ST8SIA2 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 35/526 reads (7%) | PolyPhen probably damaging (0.975); catalogued as rs1344508920; called by muse, mutect2
- STAB1 | c.7459G>A p.G2487R | Missense Mutation (SNP) | VAF 44/614 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.916); catalogued as rs1225303130, COSV58732365; called by muse, mutect2
- STAC | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 15/267 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99830383; called by muse, mutect2
- STS | c.1236G>T p.E412D | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs781652320; called by muse, mutect2, varscan2
- SVEP1 | c.5453G>A p.G1818E | Missense Mutation (SNP) | VAF 38/464 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52841807, COSV52845196; called by muse, mutect2
- SYT12 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 70/505 reads (14%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.875); catalogued as rs758277441, COSV101211069; called by muse, mutect2, varscan2
- TAS1R2 | c.1325G>A p.G442E | Missense Mutation (SNP) | VAF 26/420 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100946275; called by muse, mutect2
- TCN2 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 14/258 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1193277477; called by muse, mutect2
- TENM1 | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 35/270 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as rs1569402825, COSV100950657; called by muse, mutect2, varscan2
- TEX13C | c.2944C>T p.R982C | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.213); catalogued as rs950841810, COSV101084716; called by muse, mutect2, varscan2
- TIAM1 | c.2963C>T p.S988F | Missense Mutation (SNP) | VAF 18/362 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.459); catalogued as COSV99733864; called by muse, mutect2
- TLL2 | c.2354G>A p.G785E | Missense Mutation (SNP) | VAF 15/307 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63570719; called by muse, mutect2
- TLN2 | c.1283C>T p.S428F | Missense Mutation (SNP) | VAF 19/317 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1300976297; called by muse, mutect2
- TMEM125 | c.490G>A p.G164S | Missense Mutation (SNP) | VAF 44/545 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.155); catalogued as rs1239653730; called by muse, mutect2
- TMEM200A | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 24/360 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99758556; called by muse, mutect2
- TMEM225 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 34/395 reads (9%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as rs1310598409, COSV66692956; called by muse, mutect2
- TMEM50B | c.25C>T p.R9C | Missense Mutation (SNP) | VAF 14/390 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1048431643, COSV70278954; called by muse, mutect2
- TMPRSS11A | c.963G>A p.G321= | Splice Region (SNP) | VAF 19/244 reads (8%) | catalogued as rs757701155; called by muse, mutect2
- TNK2 | c.2161C>T p.P721S | Missense Mutation (SNP) | VAF 44/602 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.491); catalogued as rs765135399; called by muse, mutect2
- TNN | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 32/550 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.677); catalogued as rs1339983462, COSV53424926; called by muse, mutect2
- TNR | c.1628G>A p.G543E | Missense Mutation (SNP) | VAF 25/372 reads (7%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.996); catalogued as rs1388472056, COSV54887701; called by muse, mutect2
- TRAV2 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 24/285 reads (8%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.544); catalogued as rs1428178464; called by muse, mutect2
- TTN | c.84059G>A p.G28020D (on ENST00000591111; = p.G20596D on NM_003319.4) | Missense Mutation (SNP) | VAF 33/436 reads (8%) | PolyPhen probably damaging (1); catalogued as rs764756194, COSV59962653; called by muse, mutect2
- TTN | c.11371C>T p.P3791S (on ENST00000591111; = p.P3745S on NM_003319.4) | Missense Mutation (SNP) | VAF 22/390 reads (6%) | catalogued as COSV100620342; called by muse, mutect2
- TTN | c.6085G>A p.E2029K (on ENST00000591111; = p.E1983K on NM_003319.4) | Missense Mutation (SNP) | VAF 24/372 reads (6%) | PolyPhen benign (0.385); catalogued as COSV60259461; called by muse, mutect2
- UGT8 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 18/432 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.19); catalogued as rs1298078821, COSV60416276; called by muse, mutect2
- USP29 | c.1924G>A p.E642K | Missense Mutation (SNP) | VAF 17/357 reads (5%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.902); catalogued as rs868065210, COSV54143198; called by muse, mutect2
- VARS1 | c.2618C>T p.P873L | Missense Mutation (SNP) | VAF 38/474 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777369343, COSV100791876; called by muse, mutect2
- VCAN | c.5147C>T p.S1716F | Missense Mutation (SNP) | VAF 31/400 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs754070094; called by muse, mutect2
- VPS13C | c.10246C>T p.L3416F (on ENST00000644861 / NM_020821.3; = p.L3373F on NM_017684.5) | Missense Mutation (SNP) | VAF 16/282 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1303781577; called by muse, mutect2
- VPS35 | c.2263C>T p.P755S | Missense Mutation (SNP) | VAF 32/350 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.122); catalogued as rs76693948; called by muse, mutect2
- WASF3 | c.1108C>T p.P370S | Missense Mutation (SNP) | VAF 48/548 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV58969659; called by muse, mutect2
- WDR87 | c.7088G>A p.R2363K | Missense Mutation (SNP) | VAF 19/334 reads (6%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); catalogued as rs1030591182; called by muse, mutect2
- WNT16 | c.847G>A p.D283N (on ENST00000222462 / NM_057168.2; = p.D273N on NM_016087.2) | Missense Mutation (SNP) | VAF 46/304 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV55976210; called by muse, mutect2, varscan2
- WNT7A | c.573C>T p.I191= | Splice Region (SNP) | VAF 10/202 reads (5%) | catalogued as COSV99541877; called by muse, mutect2
- YLPM1 | c.2222C>T p.S741L | Missense Mutation (SNP) | VAF 21/368 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.1); catalogued as rs905468254, COSV53111754; called by muse, mutect2
- ZAN | c.5018G>A p.G1673D | Missense Mutation (SNP) | VAF 32/296 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as rs1252374355, COSV100769945; called by muse, mutect2, varscan2
- ZDHHC4 | c.741G>A p.Q247= | Splice Region (SNP) | VAF 19/154 reads (12%) | catalogued as rs748066993; called by muse, mutect2, varscan2
- ZNF30 | c.1657G>A p.G553R | Missense Mutation (SNP) | VAF 35/456 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as rs192386994; called by muse, mutect2
- ZNF333 | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 28/347 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs780002923, COSV99469123; called by muse, mutect2
- ZNF479 | c.970C>T p.P324S | Missense Mutation (SNP) | VAF 25/369 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1554400116, COSV58637230; called by muse, mutect2
- ZNF536 | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 38/629 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.193); catalogued as COSV100834850, COSV100835743; called by muse, mutect2
- ZNF546 | c.1273C>T p.H425Y | Missense Mutation (SNP) | VAF 40/335 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs369133108; called by muse, mutect2, varscan2
- ZNF713 | c.829G>A p.E277K (on ENST00000633730 / NM_001366796.2; = p.E290K on NM_182633.3) | Missense Mutation (SNP) | VAF 36/365 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV70057196; called by muse, mutect2
- ZNF773 | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 28/374 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.192); catalogued as COSV56587826; called by muse, mutect2
- ZNF780B | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 13/224 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as COSV99666124; called by muse, mutect2
- ZNF862 | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 29/430 reads (7%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.11); catalogued as COSV56225389; called by muse, mutect2
- ZSCAN20 | c.2336C>T p.S779F | Missense Mutation (SNP) | VAF 26/512 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as rs1416595464, COSV63684518; called by muse, mutect2
- ZSCAN5B | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 30/586 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.424); catalogued as COSV62000578; called by muse, mutect2
- AATF | c.1658C>T p.P553L | Missense Mutation (SNP) | VAF 18/375 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2
- ABLIM3 | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 24/394 reads (6%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.563); called by muse, mutect2
- ACAN | c.6586A>G p.T2196A | Missense Mutation (SNP) | VAF 26/416 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.175); called by muse, mutect2
- ACOD1 | c.836C>T p.S279F | Missense Mutation (SNP) | VAF 32/421 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); called by muse, mutect2
- ACTA2 | c.770T>C p.F257S | Missense Mutation (SNP) | VAF 18/312 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ACTN4 | c.570C>T p.I190= | Splice Region (SNP) | VAF 18/220 reads (8%) | called by muse, mutect2
- ADAMTS3 | c.469G>A p.G157R | Missense Mutation (SNP) | VAF 22/374 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2
- ADCY1 | c.3227C>T p.P1076L | Missense Mutation (SNP) | VAF 66/536 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ADGRG4 | c.1394C>T p.S465L | Missense Mutation (SNP) | VAF 27/243 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRV1 | c.10489C>T p.Q3497* | Nonsense Mutation (SNP) | VAF 16/290 reads (6%) | called by muse, mutect2
- ADH6 | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 21/342 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.158); called by muse, mutect2
- ADM5 | c.64A>C p.T22P | Missense Mutation (SNP) | VAF 38/388 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); called by muse, mutect2
- AFAP1L2 | c.58A>G p.I20V | Missense Mutation (SNP) | VAF 16/374 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.019); called by muse, mutect2
- AGO1 | c.2427C>G p.F809L | Missense Mutation (SNP) | VAF 23/342 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.33); called by muse, mutect2
- AHNAK2 | c.11281G>A p.D3761N | Missense Mutation (SNP) | VAF 20/444 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.714); called by muse, mutect2
- AHNAK2 | c.7562C>T p.S2521F | Missense Mutation (SNP) | VAF 31/593 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.775); called by muse, mutect2
- AKAP11 | c.3170C>T p.A1057V | Missense Mutation (SNP) | VAF 19/300 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.022); called by muse, mutect2
- AKAP12 | c.1798G>A p.G600R | Missense Mutation (SNP) | VAF 19/384 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2
- ALK | c.3787G>A p.G1263R | Missense Mutation (SNP) | VAF 24/415 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- ALPK2 | c.1565G>A p.G522E | Missense Mutation (SNP) | VAF 41/436 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- AMBN | c.1166C>T p.P389L | Missense Mutation (SNP) | VAF 31/380 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.465); called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.5930C>T p.S1977F | Missense Mutation (SNP) | VAF 28/413 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); called by muse, mutect2
- ANKRD66 | c.548T>G p.F183C | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ANO9 | c.1526C>T p.S509F | Missense Mutation (SNP) | VAF 41/342 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- ANXA1 | c.804G>A p.V268= | Splice Region (SNP) | VAF 18/298 reads (6%) | called by muse, mutect2
- ARAF | c.1168C>T p.L390F | Missense Mutation (SNP) | VAF 36/270 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- ARHGAP30 | c.1973G>A p.G658E | Missense Mutation (SNP) | VAF 32/498 reads (6%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.012); called by muse, mutect2
- ARHGEF7 | c.2347C>T p.P783S (on ENST00000646102 / NM_001354046.1; = p.P567S on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/304 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ASPH | c.1927G>T p.G643* | Nonsense Mutation (SNP) | VAF 14/322 reads (4%) | called by muse, mutect2
- ATP8A2 | c.1179A>G p.I393M | Missense Mutation (SNP) | VAF 10/207 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.066); called by muse, mutect2
- ATP8B4 | c.2581C>T p.H861Y | Missense Mutation (SNP) | VAF 18/396 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ATP9A | c.594G>A p.W198* | Nonsense Mutation (SNP) | VAF 36/370 reads (10%) | called by muse, mutect2
- ATRIP | c.1883-1G>A p.X628_splice | Splice Site (SNP) | VAF 15/275 reads (5%) | called by muse, mutect2
- ATXN2 | c.2069C>T p.P690L (on ENST00000550104; = p.P530L on NM_002973.4) | Missense Mutation (SNP) | VAF 16/304 reads (5%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.997); called by muse, mutect2
- B4GALNT3 | c.1814G>A p.G605E | Missense Mutation (SNP) | VAF 34/516 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- BCL2L14 | c.575G>A p.G192D | Missense Mutation (SNP) | VAF 22/290 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2
- BCL9L | c.4482G>A p.M1494I | Missense Mutation (SNP) | VAF 27/392 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.118); called by muse, mutect2
- BCR | c.1861-1G>A p.X621_splice | Splice Site (SNP) | VAF 29/267 reads (11%) | called by muse, mutect2, varscan2
- BEST3 | c.1373G>A p.G458E | Missense Mutation (SNP) | VAF 36/504 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0.001); called by muse, mutect2
- BHLHA15 | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 74/601 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BRD4 | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 16/309 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.141); called by muse, mutect2
- BTBD8 | c.2230G>A p.D744N (on ENST00000636805 / NM_001376131.1; = p.D231N on NM_015237.4) | Missense Mutation (SNP) | VAF 16/432 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2
- BTG4 | c.221G>A p.R74K | Missense Mutation (SNP) | VAF 25/419 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.065); called by muse, mutect2
- BTNL8 | c.938A>T p.K313I | Missense Mutation (SNP) | VAF 34/430 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.879); called by muse, mutect2
- C3 | c.1900G>A p.D634N | Missense Mutation (SNP) | VAF 24/368 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0.005); called by muse, mutect2
- CACNA1A | c.1585C>A p.L529I | Missense Mutation (SNP) | VAF 22/348 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); called by muse, mutect2
- CACNA1C | c.1907C>T p.S636F | Missense Mutation (SNP) | VAF 16/284 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CALML3 | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 38/487 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.021); called by muse, mutect2
- CCDC168 | c.11530G>A p.E3844K | Missense Mutation (SNP) | VAF 20/298 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.031); called by muse, mutect2
- CCDC80 | c.1932A>T p.E644D | Missense Mutation (SNP) | VAF 30/420 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.031); called by muse, mutect2
- CCDC81 | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 18/300 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2
- CCDC88B | c.3610G>A p.E1204K | Missense Mutation (SNP) | VAF 54/588 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- CCDC88C | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 34/422 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CD46 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 17/252 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2
- CDHR5 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 30/506 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- CENPE | c.1868T>A p.M623K | Missense Mutation (SNP) | VAF 18/274 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.042); called by muse, mutect2
- CEP152 | c.5118T>A p.F1706L (on ENST00000380950 / NM_001194998.2; = p.F1650L on NM_014985.4) | Missense Mutation (SNP) | VAF 17/207 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.03); called by muse, mutect2
- CHSY1 | c.878A>T p.H293L | Missense Mutation (SNP) | VAF 36/488 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.158); called by muse, mutect2
- CLCN1 | c.2134G>A p.D712N | Missense Mutation (SNP) | VAF 52/377 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CNBD2 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 18/366 reads (5%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.005); called by muse, mutect2
- CNTN3 | c.335G>A p.R112K | Missense Mutation (SNP) | VAF 16/327 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.021); called by muse, mutect2
- CNTNAP2 | c.3880C>T p.H1294Y | Missense Mutation (SNP) | VAF 28/680 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.093); called by muse, mutect2
- COL6A6 | c.1453G>A p.D485N | Missense Mutation (SNP) | VAF 28/418 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.412); called by muse, mutect2
- CPTP | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 24/336 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- CRTC1 | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 20/424 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2
- CSF1R | c.2053C>T p.P685S | Missense Mutation (SNP) | VAF 31/433 reads (7%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.66); called by muse, mutect2
- CSMD2 | c.4456G>A p.V1486I | Missense Mutation (SNP) | VAF 30/332 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2
- CSNK2A1 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 25/216 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- CTNNA2 | c.2710G>T p.V904L (on ENST00000402739 / NM_001282597.3; = p.V856L on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/348 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.393); called by muse, mutect2
- CXCL13 | c.169G>A p.G57R | Missense Mutation (SNP) | VAF 14/306 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CYP2R1 | c.1328T>A p.L443Q | Missense Mutation (SNP) | VAF 12/274 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.639); called by muse, mutect2
- CYP51A1 | c.965C>T p.S322F | Missense Mutation (SNP) | VAF 45/387 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DCAF1 | c.2723G>A p.G908D | Missense Mutation (SNP) | VAF 28/482 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.732); called by muse, mutect2
- DCAF12 | c.505C>T p.R169* | Nonsense Mutation (SNP) | VAF 39/388 reads (10%) | called by muse, mutect2
- DCDC1 | c.4302C>A p.F1434L (on ENST00000597505 / NM_001367979.1; = p.F541L on NM_020869.3) | Missense Mutation (SNP) | VAF 16/221 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.684); called by muse, mutect2
- DNAH10 | c.2537C>T p.S846F (on ENST00000409039; = p.S785F on NM_207437.3) | Missense Mutation (SNP) | VAF 22/450 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.188); called by muse, mutect2
- DNAH6 | c.3757G>A p.D1253N | Missense Mutation (SNP) | VAF 18/256 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.534); called by muse, mutect2
- DNAH6 | c.11309G>A p.R3770K | Missense Mutation (SNP) | VAF 23/258 reads (9%) | SIFT tolerated (0.83); PolyPhen benign (0.028); called by muse, mutect2
- DNAI1 | c.1036G>A p.D346N | Missense Mutation (SNP) | VAF 22/400 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- DPP6 | c.1217C>T p.S406F (on ENST00000377770 / NM_001364500.2; = p.S344F on NM_001936.5) | Missense Mutation (SNP) | VAF 18/432 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DPY19L3 | c.2018C>T p.P673L | Missense Mutation (SNP) | VAF 22/328 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); called by muse, mutect2
- DSEL | c.1018G>A p.A340T | Missense Mutation (SNP) | VAF 22/483 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DSEL | c.853G>T p.E285* | Nonsense Mutation (SNP) | VAF 23/543 reads (4%) | called by muse, mutect2
- ECE1 | c.1601C>A p.A534D | Missense Mutation (SNP) | VAF 13/277 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.022); called by muse, mutect2
- EEA1 | c.2779C>A p.H927N | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- EIF4G1 | c.1097C>T p.P366L (on ENST00000346169 / NM_198241.3; = p.P170L on NM_004953.5) | Missense Mutation (SNP) | VAF 29/414 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.062); called by muse, mutect2
- EMC1 | c.2281C>T p.L761F | Missense Mutation (SNP) | VAF 23/493 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- EPS15 | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 15/282 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.738); called by muse, mutect2
- FAM135B | c.2515C>T p.Q839* | Nonsense Mutation (SNP) | VAF 18/446 reads (4%) | called by muse, mutect2
- FAM135B | c.2514C>G p.N838K | Missense Mutation (SNP) | VAF 18/446 reads (4%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2
- FAM47E-STBD1 | c.1026G>A p.Q342= | Splice Region (SNP) | VAF 42/420 reads (10%) | called by muse, mutect2
- FASN | c.7214T>C p.I2405T | Missense Mutation (SNP) | VAF 41/446 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- FBN3 | c.7154C>T p.S2385F | Missense Mutation (SNP) | VAF 22/494 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2
- FBN3 | c.2295A>G p.K765= | Splice Region (SNP) | VAF 15/238 reads (6%) | called by muse, mutect2
- FGFR4 | c.2257G>A p.E753K | Missense Mutation (SNP) | VAF 24/276 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- FKRP | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 34/526 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.249); called by muse, mutect2
- FLG2 | c.2981C>T p.S994L | Missense Mutation (SNP) | VAF 20/412 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2
- FLVCR1 | c.997C>T p.P333S | Missense Mutation (SNP) | VAF 14/282 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.101); called by muse, mutect2
- FNDC1 | c.3229G>A p.G1077S | Missense Mutation (SNP) | VAF 34/483 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- FPGS | c.659G>A p.G220E | Missense Mutation (SNP) | VAF 23/448 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FPGT-TNNI3K | c.1897C>T p.P633S | Missense Mutation (SNP) | VAF 20/528 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.821); called by muse, mutect2
- FREM1 | c.131G>A p.G44E | Missense Mutation (SNP) | VAF 20/368 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- FREM2 | c.2257C>T p.H753Y | Missense Mutation (SNP) | VAF 18/404 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2
- FRMPD2 | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 31/304 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- FRMPD3 | c.399C>T p.S133= | Splice Region (SNP) | VAF 22/146 reads (15%) | called by muse, mutect2, varscan2
- FSIP2 | c.15445G>A p.E5149K | Missense Mutation (SNP) | VAF 21/348 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); called by muse, mutect2
- FURIN | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 16/350 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0.007); called by muse, mutect2
- GALNT6 | c.1085C>T p.S362F | Missense Mutation (SNP) | VAF 14/410 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- GPC3 | c.1290G>A p.E430= | Splice Region (SNP) | VAF 12/127 reads (9%) | called by muse, mutect2, varscan2
- GPT | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 22/414 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2
- GRK3 | c.1852A>G p.K618E | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- GTF3C4 | c.2184G>A p.R728= | Splice Region (SNP) | VAF 18/180 reads (10%) | called by muse, mutect2
- GZMK | c.521C>T p.T174I | Missense Mutation (SNP) | VAF 32/474 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.377); called by muse, mutect2
- HEPH | c.1828G>A p.D610N (on ENST00000343002; = p.D343N on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HRG | c.1385C>T p.P462L | Missense Mutation (SNP) | VAF 13/305 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- HTRA2 | c.259A>T p.T87S | Missense Mutation (SNP) | VAF 15/508 reads (3%) | SIFT tolerated (0.28); PolyPhen benign (0.01); called by muse, mutect2
- IDH2 | c.236T>C p.L79P | Missense Mutation (SNP) | VAF 25/376 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.741); called by muse, mutect2
- IFT140 | c.3389C>T p.S1130F | Missense Mutation (SNP) | VAF 31/393 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.235); called by muse, mutect2
- IGLV3-19 | c.257G>A p.G86E | Missense Mutation (SNP) | VAF 31/233 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- IL12RB2 | c.1829G>A p.G610E | Missense Mutation (SNP) | VAF 21/351 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- IL17RB | c.278A>G p.N93S | Missense Mutation (SNP) | VAF 22/420 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2
- IL17RD | c.1379A>G p.K460R | Missense Mutation (SNP) | VAF 34/426 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.19); called by muse, mutect2
- IMPG2 | c.2273G>A p.W758* | Nonsense Mutation (SNP) | VAF 31/458 reads (7%) | called by muse, mutect2
- IQCA1L | c.1283G>A p.R428K | Missense Mutation (SNP) | VAF 40/335 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- IRAG1 | c.2689G>A p.D897N | Missense Mutation (SNP) | VAF 25/300 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2
- IRAG1 | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 23/325 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- ITGA11 | c.469C>T p.Q157* | Nonsense Mutation (SNP) | VAF 20/231 reads (9%) | called by muse, mutect2
- ITGA11 | c.54G>A p.G18= | Splice Region (SNP) | VAF 30/338 reads (9%) | called by muse, mutect2
- ITGA9 | c.1498T>G p.F500V | Missense Mutation (SNP) | VAF 26/328 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.173); called by muse, mutect2
- ITPKC | c.350G>A p.R117K | Missense Mutation (SNP) | VAF 22/386 reads (6%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2
- JAK3 | c.3191C>T p.P1064L | Missense Mutation (SNP) | VAF 26/580 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.221); called by muse, mutect2
- KALRN | c.4537G>A p.D1513N | Missense Mutation (SNP) | VAF 24/351 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- KDM3A | c.2254C>T p.P752S | Missense Mutation (SNP) | VAF 19/358 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.067); called by muse, mutect2
- KDM3B | c.3298C>T p.P1100S | Missense Mutation (SNP) | VAF 31/337 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- KIZ | c.304C>T p.Q102* | Nonsense Mutation (SNP) | VAF 26/210 reads (12%) | called by muse, mutect2, varscan2
- KLF1 | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 19/434 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.264); called by muse, mutect2
- KRT35 | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 20/326 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.049); called by muse, mutect2
- KRTAP5-10 | c.394G>A p.G132R | Missense Mutation (SNP) | VAF 25/322 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); called by muse, mutect2
- LAMC3 | c.3016G>A p.D1006N | Missense Mutation (SNP) | VAF 42/448 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.012); called by muse, mutect2
- LHFPL4 | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 10/281 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.96); called by muse, mutect2
- LILRB4 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 40/689 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.316); called by muse, mutect2
- LMOD1 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 29/496 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- LRRC41 | c.811C>T p.R271* | Nonsense Mutation (SNP) | VAF 30/504 reads (6%) | called by muse, mutect2
- LRRC7 | c.1117C>T p.P373S (on ENST00000651989 / NM_001370785.2; = p.P340S on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/270 reads (6%) | SIFT tolerated (0.59); PolyPhen benign (0.051); called by muse, mutect2
- LURAP1L | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 18/434 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MAGEB17 | c.609G>A p.M203I | Missense Mutation (SNP) | VAF 25/306 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); called by muse, mutect2
- MAGEB18 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 37/269 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MAPK10 | c.1121G>A p.G374E (on ENST00000359221 / NM_001351625.2; = p.G412E on NM_002753.5) | Missense Mutation (SNP) | VAF 16/289 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.03); called by muse, mutect2
- MAT2A | c.406-1G>A p.X136_splice | Splice Site (SNP) | VAF 16/243 reads (7%) | called by muse, mutect2
- MGAT4D | c.210G>A p.M70I | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT tolerated (0.92); PolyPhen benign (0.009); called by muse, mutect2
- MLC1 | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 18/545 reads (3%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2
- MMP2 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 17/338 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MMP28 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 21/346 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2
- MPP6 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 22/322 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- MRPL20 | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 16/350 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.09); called by muse, mutect2
- MUC16 | c.32794G>A p.G10932R | Missense Mutation (SNP) | VAF 34/450 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); called by muse, mutect2
- MUC17 | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 14/296 reads (5%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.07); called by muse, mutect2
- MUTYH | c.1514C>T p.S505F | Missense Mutation (SNP) | VAF 25/256 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2
- MXRA5 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MYOM3 | c.2735A>C p.E912A | Missense Mutation (SNP) | VAF 24/282 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); called by muse, mutect2
- NAALADL2 | c.866G>A p.R289K | Missense Mutation (SNP) | VAF 13/262 reads (5%) | SIFT tolerated (0.67); PolyPhen benign (0.04); called by muse, mutect2
- NBPF10 | c.407C>G p.P136R | Missense Mutation (SNP) | VAF 32/585 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); called by muse, mutect2
- NDRG4 | c.733G>A p.E245K (on ENST00000570248 / NM_001378344.1; = p.E277K on NM_020465.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/327 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.009); called by muse, mutect2
- NECTIN3 | c.628C>T p.L210F | Missense Mutation (SNP) | VAF 21/446 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2
- NES | c.1681G>A p.E561K | Missense Mutation (SNP) | VAF 23/374 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.023); called by muse, mutect2
- NFIC | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 50/518 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2
- NLN | c.1624C>T p.L542F | Missense Mutation (SNP) | VAF 26/396 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2
- NLRP4 | c.1498G>A p.G500R | Missense Mutation (SNP) | VAF 20/486 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NLRP5 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 23/405 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0.001); called by muse, mutect2
- NOS1 | c.1909G>A p.E637K | Missense Mutation (SNP) | VAF 16/363 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2
- NOTCH2 | c.6959G>A p.G2320E | Missense Mutation (SNP) | VAF 43/582 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- NOX1 | c.54G>A p.W18* | Nonsense Mutation (SNP) | VAF 23/146 reads (16%) | called by muse, mutect2, varscan2
- NPAS1 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 18/375 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); called by muse, mutect2
- NR4A3 | c.712C>T p.L238F | Missense Mutation (SNP) | VAF 22/470 reads (5%) | SIFT tolerated (0.71); PolyPhen benign (0.088); called by muse, mutect2
- NRXN2 | c.4658C>T p.P1553L | Missense Mutation (SNP) | VAF 40/646 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); called by muse, mutect2
- NSUN5 | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 59/512 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- NUP210L | c.3949G>A p.E1317K | Missense Mutation (SNP) | VAF 19/243 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); called by muse, mutect2
- NUP214 | c.4631C>T p.A1544V | Missense Mutation (SNP) | VAF 25/457 reads (5%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.003); called by muse, mutect2
- OR10D3 | c.814G>A p.V272I | Missense Mutation (SNP) | VAF 19/318 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.179); called by muse, mutect2
- OR10G9 | c.848A>C p.N283T | Missense Mutation (SNP) | VAF 28/401 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.077); called by muse, mutect2
- OR11L1 | c.961C>T p.L321F | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.011); called by muse, mutect2
- OR2A5 | c.745G>A p.G249R | Missense Mutation (SNP) | VAF 38/432 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2
- OR2L13 | c.490C>T p.H164Y | Missense Mutation (SNP) | VAF 20/402 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.821); called by muse, mutect2
- OR5P2 | c.686G>A p.G229E | Missense Mutation (SNP) | VAF 22/438 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- PABPC1 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 18/284 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- PANK3 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 26/404 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.025); called by muse, mutect2
- PARD3B | c.856C>T p.H286Y | Missense Mutation (SNP) | VAF 27/420 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.05); called by muse, mutect2
- PARP1 | c.2927C>T p.S976L | Missense Mutation (SNP) | VAF 19/317 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.027); called by muse, mutect2
- PCBP2 | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 21/393 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.036); called by muse, mutect2
- PCNX1 | c.4688C>T p.S1563F | Missense Mutation (SNP) | VAF 15/405 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- PHC2 | c.527C>T p.S176F | Missense Mutation (SNP) | VAF 42/475 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.133); called by muse, mutect2
- PI3 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 31/254 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- PLA2G4D | c.1705G>A p.G569R | Missense Mutation (SNP) | VAF 18/448 reads (4%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2
- PLA2G4E | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 26/388 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PLCB1 | c.1409C>T p.S470L | Missense Mutation (SNP) | VAF 33/406 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.006); called by muse, mutect2
- PLXNA4 | c.4323G>A p.W1441* | Nonsense Mutation (SNP) | VAF 16/363 reads (4%) | called by muse, mutect2
- PLXNA4 | c.4322G>A p.W1441* | Nonsense Mutation (SNP) | VAF 16/364 reads (4%) | called by muse, mutect2
- PLXNA4 | c.260G>A p.G87E | Missense Mutation (SNP) | VAF 28/505 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- POU3F3 | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 28/497 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- PPIL6 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 11/160 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.496); called by muse, mutect2
- PPM1N | c.1279G>A p.D427N | Missense Mutation (SNP) | VAF 45/340 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRDM14 | c.668T>A p.I223N | Missense Mutation (SNP) | VAF 37/422 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2
- PRELID3B | c.392C>A p.T131N | Missense Mutation (SNP) | VAF 20/350 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.089); called by muse, mutect2
- PRG4 | c.3305G>A p.G1102E | Missense Mutation (SNP) | VAF 29/388 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.719); called by muse, mutect2
- PRKACB | c.427C>T p.H143Y | Missense Mutation (SNP) | VAF 14/264 reads (5%) | SIFT tolerated (1); PolyPhen possibly damaging (0.613); called by muse, mutect2
- PRSS37 | c.143G>A p.S48N | Missense Mutation (SNP) | VAF 36/358 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRUNE2 | c.2855C>T p.S952F | Missense Mutation (SNP) | VAF 34/411 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PSG6 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 14/306 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); called by muse, mutect2
- PTGIR | c.692G>A p.G231E | Missense Mutation (SNP) | VAF 39/530 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.392); called by muse, mutect2
- PTH2 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 38/594 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- PTPRS | c.2506C>T p.P836S | Missense Mutation (SNP) | VAF 17/482 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); called by muse, mutect2
- RAP1GDS1 | c.858T>G p.I286M (on ENST00000408927 / NM_001100427.2; = p.I287M on NM_021159.5) | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- RBM20 | c.3112C>T p.H1038Y | Missense Mutation (SNP) | VAF 18/496 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.212); called by muse, mutect2
- RCCD1 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 29/527 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- RCSD1 | c.108G>A p.E36= | Splice Region (SNP) | VAF 22/326 reads (7%) | called by muse, mutect2
- RELN | c.4069C>T p.P1357S | Missense Mutation (SNP) | VAF 43/491 reads (9%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.984); called by muse, mutect2
- REV3L | c.7480C>A p.P2494T | Missense Mutation (SNP) | VAF 28/374 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- RGPD3 | c.3185C>T p.S1062L | Missense Mutation (SNP) | VAF 23/511 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2
- RSPO1 | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 22/368 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.96); called by muse, mutect2
- RTL1 | c.2827G>A p.E943K | Missense Mutation (SNP) | VAF 18/401 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.68); called by muse, mutect2
- SAMD4A | c.2056C>T p.P686S | Missense Mutation (SNP) | VAF 13/268 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.112); called by muse, mutect2
- SCN9A | c.2101G>A p.E701K (on ENST00000303354; = p.E690K on NM_002977.3) | Missense Mutation (SNP) | VAF 13/216 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.075); called by muse, mutect2
- SEMA3C | c.1763C>T p.T588I | Missense Mutation (SNP) | VAF 32/272 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); called by mutect2, varscan2
- SEMG1 | c.860C>T p.S287L | Missense Mutation (SNP) | VAF 15/395 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); called by muse, mutect2
- SERPINE3 | c.855G>A p.W285* | Nonsense Mutation (SNP) | VAF 24/434 reads (6%) | called by muse, mutect2
- SHANK1 | c.1411C>T p.Q471* | Nonsense Mutation (SNP) | VAF 33/626 reads (5%) | called by muse, mutect2
- SIGLEC11 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 32/550 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.085); called by muse, mutect2
- SLC11A2 | c.1639T>G p.Y547D (on ENST00000394904 / NM_001379455.1; = p.Y518D on NM_000617.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/383 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC26A8 | c.447T>C p.G149= | Splice Region (SNP) | VAF 12/238 reads (5%) | called by muse, mutect2
- SLC28A3 | c.1282G>A p.D428N | Missense Mutation (SNP) | VAF 13/284 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.068); called by muse, mutect2
- SLC6A9 | c.1354C>T p.P452S (on ENST00000360584 / NM_201649.4; = p.P398S on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/710 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SMG9 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 40/630 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, mutect2
- SMIM41 | c.131C>T p.S44F | Missense Mutation (SNP) | VAF 58/736 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.692); called by muse, mutect2
- SOWAHA | c.281G>A p.G94D | Missense Mutation (SNP) | VAF 40/580 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.295); called by muse, mutect2
- SPEF2 | c.3288G>A p.W1096* | Nonsense Mutation (SNP) | VAF 14/391 reads (4%) | called by muse, mutect2
- SPTBN4 | c.4288G>A p.E1430K | Missense Mutation (SNP) | VAF 24/400 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.145); called by muse, mutect2
- SRPK2 | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 51/447 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- SSC5D | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 22/370 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.042); called by muse, mutect2
- STOML3 | c.572T>G p.I191S | Missense Mutation (SNP) | VAF 26/457 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- STYX | c.473A>T p.N158I | Missense Mutation (SNP) | VAF 12/272 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2
- SYNJ2 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 16/279 reads (6%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.551); called by muse, mutect2
- TASOR2 | c.4606G>A p.G1536S | Missense Mutation (SNP) | VAF 34/420 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.058); called by muse, mutect2
- TBC1D3B | c.1375C>T p.P459S | Missense Mutation (SNP) | VAF 50/1030 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- TENM1 | c.4603G>A p.E1535K | Missense Mutation (SNP) | VAF 35/348 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); called by muse, mutect2
- TEX13A | c.1141G>A p.D381N | Missense Mutation (SNP) | VAF 32/256 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- TEX13B | c.619G>A p.G207R | Missense Mutation (SNP) | VAF 34/274 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- THSD1 | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 32/509 reads (6%) | SIFT tolerated (0.84); PolyPhen benign (0.003); called by muse, mutect2
- TMC1 | c.272G>A p.R91K | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2
- TMCC2 | c.1793C>T p.S598F | Missense Mutation (SNP) | VAF 20/362 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- TMEM132E | c.1319T>A p.M440K (on ENST00000321639; = p.M530K on NM_001304438.2) | Missense Mutation (SNP) | VAF 16/386 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.103); called by muse, mutect2
- TMEM42 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 30/467 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2
- TMEM67 | c.713G>A p.W238* | Nonsense Mutation (SNP) | VAF 15/256 reads (6%) | called by muse, mutect2
- TMLHE | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TNFSF13B | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 29/426 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.03); called by muse, mutect2
- TNRC6C | c.2166G>A p.M722I | Missense Mutation (SNP) | VAF 26/454 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.958); called by muse, mutect2
- TNRC6C | c.2167G>A p.E723K | Missense Mutation (SNP) | VAF 26/456 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2
- TOMM40 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 31/598 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2
- TOPORS | c.1915G>A p.G639R | Missense Mutation (SNP) | VAF 29/364 reads (8%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.08); called by muse, mutect2
- TRANK1 | c.1459G>A p.G487S | Missense Mutation (SNP) | VAF 32/490 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- TRAV4 | c.280C>G p.R94G | Missense Mutation (SNP) | VAF 20/229 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.181); called by muse, mutect2
- TRIM10 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 42/656 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- TRIM43B | c.318G>A p.M106I | Missense Mutation (SNP) | VAF 21/336 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2
- TRIM64B | c.1231G>A p.D411N | Missense Mutation (SNP) | VAF 30/840 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRIM9 | c.239C>A p.S80Y | Missense Mutation (SNP) | VAF 30/444 reads (7%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.885); called by muse, mutect2
- TRIP12 | c.773C>T p.S258L | Missense Mutation (SNP) | VAF 31/497 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.916); called by muse, mutect2
- TRPS1 | c.1130A>T p.K377I (on ENST00000220888 / NM_001330599.2; = p.K390I on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/472 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.731); called by muse, mutect2
- TRPV6 | c.2092G>A p.D698N | Missense Mutation (SNP) | VAF 57/478 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TSGA13 | c.554A>G p.K185R | Missense Mutation (SNP) | VAF 31/213 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- TTN | c.12899C>T p.S4300F (on ENST00000591111; = p.S4254F on NM_003319.4) | Missense Mutation (SNP) | VAF 23/350 reads (7%) | called by muse, mutect2
- TUT4 | c.2249G>A p.G750E | Missense Mutation (SNP) | VAF 30/415 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); called by muse, mutect2
- UBR3 | c.958T>A p.S320T | Missense Mutation (SNP) | VAF 25/249 reads (10%) | SIFT tolerated (0.66); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- UNC5A | c.1105G>A p.D369N | Missense Mutation (SNP) | VAF 37/490 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2
- USP19 | c.299G>A p.G100E | Missense Mutation (SNP) | VAF 22/219 reads (10%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP24 | c.1212G>A p.M404I | Missense Mutation (SNP) | VAF 14/290 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2
- VPS13D | c.8104T>G p.S2702A | Missense Mutation (SNP) | VAF 35/400 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.565); called by muse, mutect2
- WAC | c.1734T>A p.H578Q | Missense Mutation (SNP) | VAF 13/334 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); called by muse, mutect2
- WFDC11 | c.188A>G p.D63G | Missense Mutation (SNP) | VAF 27/400 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.023); called by muse, mutect2
- WNT3A | c.124T>C p.C42R | Missense Mutation (SNP) | VAF 30/295 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ZBTB40 | c.2758C>T p.P920S | Missense Mutation (SNP) | VAF 22/433 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZDHHC20 | c.941G>A p.R314K | Missense Mutation (SNP) | VAF 18/271 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZNF211 | c.535C>T p.H179Y (on ENST00000347302 / NM_198855.4; = p.H192Y on NM_006385.5) | Missense Mutation (SNP) | VAF 24/448 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- ZNF341 | c.1519C>T p.L507F (on ENST00000375200 / NM_001282935.1; = p.L500F on NM_032819.4) | Missense Mutation (SNP) | VAF 44/514 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2
- ZNF391 | c.434C>T p.S145F | Missense Mutation (SNP) | VAF 30/441 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.337); called by muse, mutect2
- ZNF445 | c.1577C>T p.S526F | Missense Mutation (SNP) | VAF 29/460 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- ZNF557 | c.1046C>T p.S349F (on ENST00000414706 / NM_001044388.2; = p.S356F on NM_024341.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/374 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); called by muse, mutect2
- ZNF669 | c.556T>A p.L186I | Missense Mutation (SNP) | VAF 32/484 reads (7%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.899); called by muse, mutect2
- ZNF780B | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 13/218 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.339); called by muse, mutect2
- ZNF837 | c.985G>A p.G329S | Missense Mutation (SNP) | VAF 40/534 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.118); called by muse, mutect2
- ZNHIT6 | c.1204C>T p.Q402* | Nonsense Mutation (SNP) | VAF 26/334 reads (8%) | called by muse, mutect2
- ZSCAN20 | c.2987T>G p.F996C | Missense Mutation (SNP) | VAF 29/450 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZSCAN5B | c.814T>A p.S272T | Missense Mutation (SNP) | VAF 31/587 reads (5%) | SIFT tolerated (0.71); PolyPhen benign (0.049); called by muse, mutect2
- ABCA12 | c.4881C>T p.V1627= (on ENST00000272895 / NM_173076.3; = p.V1309= on NM_015657.3) | Silent (SNP) | VAF 30/373 reads (8%) | called by muse, mutect2
- AC007906.2 | c.150A>T p.P50= | Silent (SNP) | VAF 23/215 reads (11%) | called by muse, mutect2, varscan2
- ACKR2 | c.624C>T p.L208= | Silent (SNP) | VAF 20/463 reads (4%) | called by muse, mutect2
- ACSBG1 | c.1212C>T p.A404= | Silent (SNP) | VAF 42/554 reads (8%) | called by muse, mutect2
- ACTL7B | c.1071G>A p.R357= | Silent (SNP) | VAF 37/393 reads (9%) | catalogued as rs901751354, COSV65927768; called by muse, mutect2
- ADAMTSL1 | c.2631G>A p.R877= | Silent (SNP) | VAF 30/503 reads (6%) | called by muse, mutect2
- ADCY7 | c.1977G>A p.E659= | Silent (SNP) | VAF 29/382 reads (8%) | called by muse, mutect2
- ADGRB1 | c.324C>T p.L108= | Silent (SNP) | VAF 38/564 reads (7%) | catalogued as rs774061860; called by muse, mutect2
- ADGRG4 | c.798C>T p.S266= | Silent (SNP) | VAF 24/235 reads (10%) | called by muse, mutect2
- ADGRV1 | c.2394C>T p.I798= | Silent (SNP) | VAF 20/278 reads (7%) | catalogued as rs986521082, COSV67983055; called by muse, mutect2
- AGBL4 | c.849G>A p.L283= | Silent (SNP) | VAF 9/185 reads (5%) | called by muse, mutect2
- AKAP17A | c.138C>T p.I46= | Silent (SNP) | VAF 52/735 reads (7%) | catalogued as rs1475689303; called by muse, mutect2
- ALPK1 | c.1710C>T p.F570= | Silent (SNP) | VAF 20/346 reads (6%) | catalogued as COSV51584502; called by muse, mutect2
- ANKRD18A | c.237C>T p.G79= | Silent (SNP) | VAF 18/415 reads (4%) | called by muse, mutect2
- AP1B1 | c.1740C>T p.A580= | Silent (SNP) | VAF 61/433 reads (14%) | called by muse, mutect2, varscan2
- AP5B1 | c.2226C>T p.A742= | Silent (SNP) | VAF 38/542 reads (7%) | catalogued as rs778968376; called by muse, mutect2
- AP5B1 | c.1374C>T p.P458= | Silent (SNP) | VAF 48/502 reads (10%) | called by muse, mutect2
- ARHGAP19 | c.648C>T p.T216= | Silent (SNP) | VAF 17/319 reads (5%) | called by muse, mutect2
- ARHGEF11 | c.1452G>A p.G484= | Silent (SNP) | VAF 18/432 reads (4%) | catalogued as COSV100810410; called by muse, mutect2
- ARL5C | c.348G>A p.Q116= | Silent (SNP) | VAF 21/257 reads (8%) | called by muse, mutect2
- ARVCF | c.972C>T p.P324= | Silent (SNP) | VAF 57/519 reads (11%) | called by muse, mutect2, varscan2
- ASPM | c.1365A>G p.V455= | Silent (SNP) | VAF 27/321 reads (8%) | called by muse, mutect2
- ATF4 | c.465C>T p.A155= | Silent (SNP) | VAF 23/420 reads (5%) | catalogued as rs1226753256; called by muse, mutect2
- ATP1A3 | c.3021C>T p.I1007= (on ENST00000545399 / NM_001256214.2; = p.I994= on NM_152296.5) | Silent (SNP) | VAF 14/312 reads (4%) | called by muse, mutect2
- AXIN2 | c.486G>A p.K162= | Silent (SNP) | VAF 17/383 reads (4%) | catalogued as rs1555583428; ClinVar: likely benign; called by muse, mutect2
- AXL | c.2040G>A p.L680= (on ENST00000301178 / NM_021913.5; = p.L671= on NM_001699.6) | Silent (SNP) | VAF 16/270 reads (6%) | called by muse, mutect2
- B3GALNT1 | c.90C>T p.F30= | Silent (SNP) | VAF 30/402 reads (7%) | called by muse, mutect2
- BCAN | c.1632C>T p.P544= | Silent (SNP) | VAF 28/380 reads (7%) | catalogued as rs1393062683; called by muse, mutect2
- BDKRB2 | c.204C>T p.F68= | Silent (SNP) | VAF 26/344 reads (8%) | catalogued as rs943088316, COSV60014259; called by muse, mutect2
- BHMT2 | c.492C>T p.V164= | Silent (SNP) | VAF 34/343 reads (10%) | catalogued as COSV99670246; called by muse, mutect2
- BPTF | c.690C>T p.P230= | Silent (SNP) | VAF 19/345 reads (6%) | called by muse, mutect2
- BRD2 | c.252G>A p.K84= | Silent (SNP) | VAF 48/654 reads (7%) | catalogued as rs1463130865; called by muse, mutect2
- BRD4 | c.18C>T p.G6= | Silent (SNP) | VAF 16/302 reads (5%) | called by muse, mutect2
- BRINP3 | c.288C>T p.F96= | Silent (SNP) | VAF 23/417 reads (6%) | catalogued as rs867310371, COSV66511698, COSV66528585; called by muse, mutect2
- BTNL2 | c.1167G>A p.Q389= | Silent (SNP) | VAF 36/481 reads (7%) | called by muse, mutect2
- BTNL3 | c.627C>T p.H209= | Silent (SNP) | VAF 28/353 reads (8%) | called by muse, mutect2
- C15orf39 | c.144C>T p.F48= | Silent (SNP) | VAF 25/475 reads (5%) | called by muse, mutect2
- C16orf46 | c.1116C>T p.F372= | Silent (SNP) | VAF 27/388 reads (7%) | called by muse, mutect2
- CA1 | c.66C>T p.P22= | Silent (SNP) | VAF 18/320 reads (6%) | called by muse, mutect2
- CACNA1S | c.2940C>T p.P980= | Silent (SNP) | VAF 37/404 reads (9%) | called by muse, mutect2
- CACNA2D2 | c.1188C>T p.I396= | Silent (SNP) | VAF 32/422 reads (8%) | called by muse, mutect2
- CALHM3 | c.885G>A p.R295= | Silent (SNP) | VAF 52/576 reads (9%) | catalogued as rs1322628197; called by muse, mutect2
- CCDC32 | c.357G>A p.K119= | Silent (SNP) | VAF 31/451 reads (7%) | called by muse, mutect2
- CCL28 | c.129G>A p.L43= | Silent (SNP) | VAF 22/382 reads (6%) | called by muse, mutect2
- CD8B2 | c.163C>T p.L55= | Silent (SNP) | VAF 38/456 reads (8%) | called by muse, mutect2
- CDCP1 | c.1275G>A p.R425= | Silent (SNP) | VAF 26/348 reads (7%) | catalogued as COSV56104630; called by muse, mutect2
- CDK14 | c.609G>A p.K203= (on ENST00000380050 / NM_001287135.2; = p.K185= on NM_012395.3) | Silent (SNP) | VAF 16/308 reads (5%) | catalogued as COSV56055783; called by muse, mutect2
- CDRT15L2 | c.51A>G p.G17= | Silent (SNP) | VAF 18/343 reads (5%) | called by muse, mutect2
- CEACAM16 | c.924C>T p.V308= | Silent (SNP) | VAF 25/307 reads (8%) | catalogued as rs537505779; called by muse, mutect2
- CENPJ | c.909G>A p.Q303= | Silent (SNP) | VAF 15/306 reads (5%) | called by muse, mutect2
- CFAP20DC | c.828G>A p.R276= (on ENST00000482387 / NM_001351530.2; = p.R151= on NM_198463.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 15/392 reads (4%) | catalogued as rs1257346841; called by muse, mutect2
- CHD6 | c.7788G>A p.Q2596= | Silent (SNP) | VAF 46/432 reads (11%) | catalogued as rs753815158; called by muse, mutect2, varscan2
- CHKA | c.1098C>T p.I366= | Silent (SNP) | VAF 20/260 reads (8%) | called by muse, mutect2
- CHST6 | c.711C>T p.P237= | Silent (SNP) | VAF 52/612 reads (8%) | catalogued as rs1435150985; called by muse, mutect2
- CLEC20A | c.561G>A p.L187= | Silent (SNP) | VAF 31/244 reads (13%) | called by muse, mutect2, varscan2
- CMBL | c.282C>T p.F94= | Silent (SNP) | VAF 21/347 reads (6%) | catalogued as COSV56983095; called by muse, mutect2
- CNTNAP1 | c.2109C>T p.F703= | Silent (SNP) | VAF 18/418 reads (4%) | called by muse, mutect2
- COL11A1 | c.5028G>A p.K1676= | Silent (SNP) | VAF 8/249 reads (3%) | called by muse, mutect2
- COL6A3 | c.3744C>T p.F1248= | Silent (SNP) | VAF 44/466 reads (9%) | catalogued as COSV99796842; called by muse, mutect2
- CPLX1 | c.171G>A p.A57= | Silent (SNP) | VAF 30/514 reads (6%) | catalogued as rs951400865; called by muse, mutect2
- CR1 | c.933G>A p.R311= (on ENST00000367051; = p.R761= on NM_000651.6) | Silent (SNP) | VAF 28/474 reads (6%) | called by muse, mutect2
- CRELD2 | c.75C>T p.A25= | Silent (SNP) | VAF 42/545 reads (8%) | called by muse, mutect2
- CSMD2 | c.1839G>A p.E613= | Silent (SNP) | VAF 24/471 reads (5%) | catalogued as COSV99595199; called by muse, mutect2
- CUZD1 | c.18G>A p.R6= | Silent (SNP) | VAF 28/284 reads (10%) | called by muse, mutect2
- CYP2F1 | c.984C>T p.I328= | Silent (SNP) | VAF 24/384 reads (6%) | catalogued as COSV58527010; called by muse, mutect2
- DCAF12L1 | c.1146C>T p.F382= | Silent (SNP) | VAF 28/243 reads (12%) | catalogued as COSV64421716; called by muse, mutect2, varscan2
- DCLK3 | c.294G>A p.G98= | Silent (SNP) | VAF 34/504 reads (7%) | catalogued as rs267599776, COSV69362899; called by muse, mutect2
- DIDO1 | c.4026C>T p.L1342= | Silent (SNP) | VAF 38/423 reads (9%) | called by muse, mutect2
- DNAH12 | c.6504G>A p.R2168= (on ENST00000351747; = p.R2187= on NM_001366028.2) | Silent (SNP) | VAF 12/172 reads (7%) | catalogued as COSV61059336; called by muse, mutect2
- DNAH6 | c.5829C>T p.I1943= | Silent (SNP) | VAF 24/356 reads (7%) | called by muse, mutect2
- DNAH9 | c.2862C>T p.T954= | Silent (SNP) | VAF 26/506 reads (5%) | called by muse, mutect2
- DNAI1 | c.1035G>A p.R345= | Silent (SNP) | VAF 22/396 reads (6%) | catalogued as COSV54280537; called by muse, mutect2
- DOCK3 | c.1566C>T p.L522= | Silent (SNP) | VAF 16/331 reads (5%) | catalogued as COSV56518041, COSV99809893; called by muse, mutect2
- DOCK3 | c.2820C>T p.I940= | Silent (SNP) | VAF 20/296 reads (7%) | called by muse, mutect2
- DOCK3 | c.5490G>A p.V1830= | Silent (SNP) | VAF 21/414 reads (5%) | called by muse, mutect2
- DPP4 | c.1429C>T p.L477= | Silent (SNP) | VAF 26/396 reads (7%) | called by muse, mutect2
- DYSF | c.5436C>T p.F1812= | Silent (SNP) | VAF 14/288 reads (5%) | catalogued as COSV99246814; called by muse, mutect2
- DZIP3 | c.1677C>T p.S559= | Silent (SNP) | VAF 26/330 reads (8%) | catalogued as COSV64313234; called by muse, mutect2
- EBAG9 | c.219C>T p.I73= | Silent (SNP) | VAF 32/429 reads (7%) | catalogued as rs759484343, COSV61753018; called by muse, mutect2
- EDNRA | c.633C>T p.I211= | Silent (SNP) | VAF 32/418 reads (8%) | catalogued as rs1187538994; called by muse, mutect2
- EIF2D | c.1212C>T p.S404= | Silent (SNP) | VAF 18/316 reads (6%) | catalogued as rs1197629339; called by muse, mutect2
- ELAPOR1 | c.1305G>A p.T435= | Silent (SNP) | VAF 24/290 reads (8%) | called by muse, mutect2
- ELOVL1 | c.786C>T p.P262= | Silent (SNP) | VAF 24/356 reads (7%) | catalogued as COSV60522250; called by muse, mutect2
- EMC1 | c.2280C>T p.F760= | Silent (SNP) | VAF 23/491 reads (5%) | called by muse, mutect2
- EPB41L1 | c.1584G>A p.R528= | Silent (SNP) | VAF 41/474 reads (9%) | called by muse, mutect2
- EPPK1 | c.2886C>A p.A962= | Silent (SNP) | VAF 35/514 reads (7%) | called by muse, mutect2
- ERN1 | c.1959G>A p.V653= | Silent (SNP) | VAF 12/267 reads (4%) | called by muse, mutect2
- EXOC3 | c.153C>T p.I51= | Silent (SNP) | VAF 26/303 reads (9%) | called by muse, mutect2
- EXOC4 | c.705C>T p.L235= | Silent (SNP) | VAF 32/310 reads (10%) | catalogued as COSV99556167; called by muse, mutect2
- FAM20B | c.867C>T p.D289= | Silent (SNP) | VAF 28/426 reads (7%) | called by muse, mutect2
- FAM78B | c.384C>T p.T128= | Silent (SNP) | VAF 36/494 reads (7%) | catalogued as rs1401604895, COSV100597577; called by muse, mutect2
- FAT3 | c.10983C>T p.F3661= | Silent (SNP) | VAF 17/238 reads (7%) | catalogued as rs771480729, COSV53081477; called by muse, mutect2
- FBN1 | c.4674C>T p.S1558= | Silent (SNP) | VAF 20/496 reads (4%) | catalogued as rs1263149337; called by muse, mutect2
- FBN3 | c.6705C>T p.V2235= | Silent (SNP) | VAF 34/588 reads (6%) | catalogued as COSV54461536; called by muse, mutect2
- FER1L5 | c.708G>A p.G236= (on ENST00000623019; = p.G253= on NM_001293083.2) | Silent (SNP) | VAF 14/318 reads (4%) | called by muse, mutect2
- FEZ2 | c.673C>T p.L225= | Silent (SNP) | VAF 16/305 reads (5%) | called by muse, mutect2
- FFAR3 | c.597C>T p.I199= | Silent (SNP) | VAF 28/667 reads (4%) | catalogued as rs1249010031, COSV100588327; called by muse, mutect2
- FLI1 | c.477C>T p.F159= | Silent (SNP) | VAF 37/438 reads (8%) | catalogued as rs201473472; called by muse, mutect2
- FNDC1 | c.405C>T p.I135= | Silent (SNP) | VAF 23/262 reads (9%) | catalogued as rs775301335; called by muse, mutect2
- FOXE1 | c.672C>T p.F224= | Silent (SNP) | VAF 19/412 reads (5%) | catalogued as COSV64300968; called by muse, mutect2
- FOXI1 | c.795G>A p.E265= | Silent (SNP) | VAF 42/506 reads (8%) | catalogued as rs756749477, COSV60388243; called by muse, mutect2
- FREM3 | c.6138C>T p.I2046= | Silent (SNP) | VAF 26/358 reads (7%) | catalogued as rs757757997, COSV61678663; called by muse, mutect2
- GABRA5 | c.858C>T p.V286= | Silent (SNP) | VAF 19/256 reads (7%) | catalogued as rs1010086417, COSV59477606; called by muse, mutect2
- GABRB2 | c.945C>T p.F315= | Silent (SNP) | VAF 38/426 reads (9%) | catalogued as rs79319310, COSV50936521; called by muse, mutect2
- GCK | c.21G>A p.R7= | Silent (SNP) | VAF 19/369 reads (5%) | called by muse, mutect2
- GET1-SH3BGR | c.387C>T p.I129= | Silent (SNP) | VAF 22/335 reads (7%) | catalogued as rs887325531, COSV61322335; called by muse, mutect2
- GLIPR1L1 | c.75C>T p.I25= | Silent (SNP) | VAF 21/490 reads (4%) | called by muse, mutect2
- GMEB2 | c.414C>T p.T138= | Silent (SNP) | VAF 29/298 reads (10%) | catalogued as COSV99823407; called by muse, mutect2, varscan2
- GNPAT | c.1821C>T p.F607= | Silent (SNP) | VAF 14/278 reads (5%) | called by muse, mutect2
- GOLGA8M | c.441G>A p.T147= | Silent (SNP) | VAF 22/618 reads (4%) | catalogued as rs948184217; called by muse, mutect2
- GORAB | c.96G>A p.K32= | Silent (SNP) | VAF 23/380 reads (6%) | catalogued as COSV100883751; called by muse, mutect2
- GPC6 | c.507G>A p.L169= | Silent (SNP) | VAF 24/464 reads (5%) | called by muse, mutect2
- GPT | c.1023G>A p.L341= | Silent (SNP) | VAF 22/494 reads (4%) | called by muse, mutect2
- GTPBP1 | c.288C>T p.V96= | Silent (SNP) | VAF 39/286 reads (14%) | catalogued as rs781328059; called by muse, mutect2, varscan2
- HAUS5 | c.1839C>T p.S613= | Silent (SNP) | VAF 23/409 reads (6%) | called by muse, mutect2
- HAUS5 | c.1840C>T p.L614= | Silent (SNP) | VAF 22/408 reads (5%) | called by muse, mutect2
- HBS1L | c.1479C>T p.S493= | Silent (SNP) | VAF 28/361 reads (8%) | catalogued as rs762333191; called by muse, mutect2
- HOOK2 | c.1818G>A p.K606= | Silent (SNP) | VAF 23/380 reads (6%) | catalogued as rs1438068002; called by muse, mutect2
- HSD11B1 | c.24C>T p.L8= | Silent (SNP) | VAF 18/255 reads (7%) | catalogued as COSV54826844; called by muse, mutect2
- HYDIN | c.12153C>T p.F4051= | Silent (SNP) | VAF 14/258 reads (5%) | catalogued as COSV66642903; called by muse, mutect2
- IDUA | c.93G>A p.L31= | Silent (SNP) | VAF 49/562 reads (9%) | called by muse, mutect2
- IGHV1OR21-1 | c.21C>T p.I7= | Silent (SNP) | VAF 22/418 reads (5%) | called by muse, mutect2
- IGSF10 | c.552C>T p.I184= | Silent (SNP) | VAF 32/419 reads (8%) | catalogued as COSV56792153; called by muse, mutect2
- IGSF21 | c.1182G>A p.G394= | Silent (SNP) | VAF 18/471 reads (4%) | called by muse, mutect2
- IL17RA | c.273C>T p.F91= | Silent (SNP) | VAF 20/464 reads (4%) | called by muse, mutect2
- IL36RN | c.165C>T p.S55= | Silent (SNP) | VAF 31/441 reads (7%) | called by muse, mutect2
- INSC | c.177C>G p.S59= | Silent (SNP) | VAF 24/310 reads (8%) | catalogued as COSV101088985, COSV65412969; called by muse, mutect2
- IRF7 | c.1341C>T p.F447= (on ENST00000397566; = p.F434= on NM_001572.5) | Silent (SNP) | VAF 42/449 reads (9%) | catalogued as rs762797158; called by muse, mutect2
- IRS4 | c.447C>T p.T149= | Silent (SNP) | VAF 25/205 reads (12%) | catalogued as rs183046486; called by muse, mutect2, varscan2
- ITIH4 | c.1305C>T p.G435= | Silent (SNP) | VAF 28/402 reads (7%) | called by muse, mutect2
- KCNH2 | c.2856C>T p.P952= | Silent (SNP) | VAF 78/716 reads (11%) | called by muse, mutect2
- KCNJ12 | c.1125C>T p.F375= | Silent (SNP) | VAF 38/831 reads (5%) | called by muse, mutect2
- KIAA1671 | c.3387C>T p.A1129= | Silent (SNP) | VAF 32/410 reads (8%) | called by muse, mutect2
- KIAA1958 | c.1179C>T p.S393= | Silent (SNP) | VAF 16/178 reads (9%) | catalogued as rs1217138368; called by muse, mutect2, varscan2
- KIF1C | c.2079C>T p.S693= | Silent (SNP) | VAF 20/390 reads (5%) | called by muse, mutect2
- KPTN | c.979C>T p.L327= | Silent (SNP) | VAF 34/382 reads (9%) | called by muse, mutect2
- KPTN | c.978C>T p.V326= | Silent (SNP) | VAF 36/385 reads (9%) | catalogued as rs1238871059; called by muse, mutect2
- KRT75 | c.105C>T p.V35= | Silent (SNP) | VAF 48/480 reads (10%) | called by muse, mutect2
- KSR2 | c.2268C>T p.I756= | Silent (SNP) | VAF 19/267 reads (7%) | catalogued as COSV56665231, COSV56677971; called by muse, mutect2
- LCE5A | c.249G>A p.Q83= | Silent (SNP) | VAF 28/546 reads (5%) | called by muse, mutect2
- LEUTX | c.378C>T p.A126= | Silent (SNP) | VAF 15/320 reads (5%) | catalogued as rs1389408322; called by muse, mutect2
- LGALS4 | c.285C>T p.F95= | Silent (SNP) | VAF 35/450 reads (8%) | catalogued as rs752954786; called by muse, mutect2
- LHFPL4 | c.21C>T p.A7= | Silent (SNP) | VAF 11/287 reads (4%) | called by muse, mutect2
- LILRB4 | c.651C>T p.V217= | Silent (SNP) | VAF 21/285 reads (7%) | called by muse, mutect2
- LOXHD1 | c.6234C>T p.A2078= (on ENST00000642948; = p.A2016= on NM_144612.7) | Silent (SNP) | VAF 24/394 reads (6%) | called by muse, mutect2
- LPAR1 | c.474G>A p.R158= | Silent (SNP) | VAF 35/426 reads (8%) | catalogued as rs1053720841, COSV62689270; called by muse, mutect2
- LRP4 | c.708C>T p.F236= | Silent (SNP) | VAF 33/337 reads (10%) | catalogued as COSV66135710; called by muse, mutect2
- LRPPRC | c.2997C>T p.I999= | Silent (SNP) | VAF 11/261 reads (4%) | catalogued as rs1278542435; called by muse, mutect2
- LRRC41 | c.810C>T p.S270= | Silent (SNP) | VAF 30/508 reads (6%) | called by muse, mutect2
- LRRC70 | c.987C>T p.I329= | Silent (SNP) | VAF 15/311 reads (5%) | called by muse, mutect2
- LRRK1 | c.156C>T p.S52= | Silent (SNP) | VAF 32/538 reads (6%) | called by muse, mutect2
- MAP3K6 | c.1767C>T p.F589= | Silent (SNP) | VAF 30/438 reads (7%) | called by muse, mutect2
- MASP1 | c.93C>T p.I31= | Silent (SNP) | VAF 26/506 reads (5%) | called by muse, mutect2
- MAST1 | c.963C>T p.P321= | Silent (SNP) | VAF 34/551 reads (6%) | catalogued as COSV52246132; called by muse, mutect2
- MAST1 | c.1678C>T p.L560= | Silent (SNP) | VAF 32/453 reads (7%) | catalogued as COSV99263154; called by muse, mutect2
- MCM8 | c.1932G>A p.K644= | Silent (SNP) | VAF 18/248 reads (7%) | called by muse, mutect2
- MED18 | c.447C>T p.F149= | Silent (SNP) | VAF 36/532 reads (7%) | catalogued as COSV65790309; called by muse, mutect2
- MFNG | c.885G>A p.E295= | Silent (SNP) | VAF 38/360 reads (11%) | called by muse, mutect2, varscan2
- MGA | c.6756C>T p.A2252= (on ENST00000219905 / NM_001164273.1; = p.A2043= on NM_001080541.2) | Silent (SNP) | VAF 25/388 reads (6%) | catalogued as rs1336846017; called by muse, mutect2
- MINDY4B | c.1302G>A p.R434= | Silent (SNP) | VAF 21/437 reads (5%) | called by muse, mutect2
- MROH6 | c.141C>T p.S47= | Silent (SNP) | VAF 42/679 reads (6%) | catalogued as rs1160041931; called by muse, mutect2
- MTCL1 | c.4872G>A p.K1624= (on ENST00000306329 / NM_001378206.1; = p.K1305= on NM_015210.4) | Silent (SNP) | VAF 32/354 reads (9%) | called by muse, mutect2
- MYH4 | c.1317C>T p.F439= | Silent (SNP) | VAF 33/489 reads (7%) | catalogued as rs772119364, COSV99702067; called by muse, mutect2
- MYO18B | c.1806C>T p.T602= | Silent (SNP) | VAF 47/452 reads (10%) | catalogued as rs760158796; called by muse, mutect2, varscan2
- MYO5C | c.4899C>T p.P1633= | Silent (SNP) | VAF 22/465 reads (5%) | catalogued as rs1248841845; called by muse, mutect2
- MYO9B | c.3327C>T p.S1109= | Silent (SNP) | VAF 36/531 reads (7%) | catalogued as COSV101261388; called by muse, mutect2
- NCAM2 | c.1905G>A p.K635= | Silent (SNP) | VAF 11/242 reads (5%) | called by muse, mutect2
- NCKAP5 | c.1698G>A p.Q566= | Silent (SNP) | VAF 23/440 reads (5%) | called by muse, mutect2
- NEFH | c.726C>T p.L242= | Silent (SNP) | VAF 61/524 reads (12%) | catalogued as rs560344725; called by muse, mutect2, varscan2
- NELL2 | c.2085G>A p.R695= | Silent (SNP) | VAF 16/419 reads (4%) | catalogued as rs1565866264, COSV61585696; called by muse, mutect2
- NFKBIB | c.732C>T p.P244= | Silent (SNP) | VAF 36/419 reads (9%) | called by muse, mutect2
- NIT1 | c.831C>T p.P277= | Silent (SNP) | VAF 29/528 reads (5%) | catalogued as rs1363958459; called by muse, mutect2
- NLN | c.1626C>T p.L542= | Silent (SNP) | VAF 26/397 reads (7%) | called by muse, mutect2
- NLRP1 | c.1752C>T p.T584= | Silent (SNP) | VAF 30/364 reads (8%) | called by muse, mutect2
- NOD1 | c.660C>T p.A220= | Silent (SNP) | VAF 47/486 reads (10%) | called by muse, mutect2
- NOLC1 | c.918C>T p.T306= | Silent (SNP) | VAF 20/360 reads (6%) | called by muse, mutect2
- NUP188 | c.4080G>A p.Q1360= | Silent (SNP) | VAF 23/443 reads (5%) | called by muse, mutect2
- OBSCN | c.8556G>A p.R2852= | Silent (SNP) | VAF 27/566 reads (5%) | called by muse, mutect2
- OMP | c.147G>A p.A49= | Silent (SNP) | VAF 28/473 reads (6%) | catalogued as rs1389068584, COSV53686870; called by muse, mutect2
- OPN5 | c.1023G>A p.R341= | Silent (SNP) | VAF 18/324 reads (6%) | called by muse, mutect2
- OR10A7 | c.621C>T p.I207= | Silent (SNP) | VAF 16/298 reads (5%) | catalogued as COSV58278223; called by muse, mutect2
- OR10AC1 | c.138C>T p.I46= | Silent (SNP) | VAF 46/419 reads (11%) | catalogued as rs1459719252; called by muse, mutect2, varscan2
- OR13J1 | c.906G>A p.R302= | Silent (SNP) | VAF 26/403 reads (6%) | called by muse, mutect2
- OR1B1 | c.666C>T p.L222= | Silent (SNP) | VAF 16/426 reads (4%) | called by muse, mutect2
- OR2AJ1 | c.564C>T p.S188= | Silent (SNP) | VAF 18/422 reads (4%) | called by muse, mutect2
- OR2M5 | c.183C>T p.F61= | Silent (SNP) | VAF 30/505 reads (6%) | catalogued as COSV63546300; called by muse, mutect2
- OR2T1 | c.276C>T p.S92= | Silent (SNP) | VAF 43/710 reads (6%) | catalogued as rs773058473, COSV100822367; called by muse, mutect2
- OR2T2 | c.316C>T p.L106= | Silent (SNP) | VAF 34/1280 reads (3%) | catalogued as COSV61617972; called by muse, mutect2
- OR4C16 | c.180C>T p.F60= | Silent (SNP) | VAF 32/346 reads (9%) | catalogued as rs1005210017, COSV58941265; called by muse, mutect2
- OR5A2 | c.144C>T p.A48= | Silent (SNP) | VAF 11/376 reads (3%) | called by muse, mutect2
- OR5AC2 | c.114C>T p.L38= | Silent (SNP) | VAF 25/413 reads (6%) | catalogued as COSV62279443; called by muse, mutect2
- PAPPA | c.3993G>A p.E1331= | Silent (SNP) | VAF 23/416 reads (6%) | called by muse, mutect2
- PCK1 | c.768G>A p.K256= | Silent (SNP) | VAF 30/296 reads (10%) | catalogued as rs1332667952; called by muse, mutect2, varscan2
- PCNX2 | c.3867C>T p.F1289= | Silent (SNP) | VAF 18/389 reads (5%) | catalogued as rs1444491564, COSV50782111; called by muse, mutect2
- PCNX3 | c.855G>A p.R285= | Silent (SNP) | VAF 48/542 reads (9%) | catalogued as COSV100482691; called by muse, mutect2
- PDE6B | c.849G>A p.E283= | Silent (SNP) | VAF 18/352 reads (5%) | catalogued as COSV55324173; called by muse, mutect2
- PDZD4 | c.330G>A p.A110= | Silent (SNP) | VAF 20/262 reads (8%) | catalogued as rs782163983; called by muse, mutect2
- PHF7 | c.525C>T p.I175= | Silent (SNP) | VAF 14/362 reads (4%) | called by muse, mutect2
- PIBF1 | c.316T>C p.L106= | Silent (SNP) | VAF 22/334 reads (7%) | called by muse, mutect2
- PKP1 | c.492G>A p.R164= | Silent (SNP) | VAF 32/509 reads (6%) | called by muse, mutect2
- PKP3 | c.1836C>T p.N612= | Silent (SNP) | VAF 35/547 reads (6%) | called by muse, mutect2
- PLCB1 | c.3561C>T p.S1187= | Silent (SNP) | VAF 26/422 reads (6%) | catalogued as COSV62054388; called by muse, mutect2
137 further variants in this file (0 protein-altering or splice-affecting, 100 silent, 37 other) are not listed here.
